Gene-level copy-number profile of tumor specimen TCGA-77-7141-01A from TCGA case TCGA-77-7141, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 64.6 years (23,584 days).
Specimen TCGA-77-7141-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.1ea2592c-f849-421d-8b48-b05d85917a1d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-77-7141-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/83e8f3eb-31d1-46c6-a411-4174d6aec932

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 65; copy number 1: 346; copy number 2: 18,236; copy number 3: 17,870; copy number 4: 10,820; copy number 5: 6,717; copy number 6: 3,615; copy number 7: 473; copy number 9: 1,339; copy number 10: 171; copy number 11: 49; copy number 12: 1; copy number 16: 6; copy number 17: 52; copy number 21: 44; copy number 48: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-77-7141-01A-11D-2041-01): tumor purity 0.61, ploidy 3.3, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 65 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:14,475–1,550,103, 31 genes: WASHC1, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4, CBWD1, AL158832.2, DOCK8-AS1, DOCK8, AL158832.1, AL161725.1, KANK1, RPL12P25, AL161725.2, AL392089.1, RNU6-1327P, EIF1P1, AL136979.1, DMRT1, DMRT3, RNU6-1073P, H3P29, AL358976.1, LINC01230, DMRT2, AL356498.1, RPS27AP14, AL358934.1, RNA5SP279, AL358053.1.
- chr9:21,638,285–24,088,051, 34 genes: H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,142 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:118,883,046–121,580,524, 78 genes, copy number 7 (broad region; genes not listed).
- chr1:169,849,631–169,894,267, 2 genes, copy number 10: SCYL3, RN7SL333P.
- chr3:134,170,487–198,222,513, 1,106 genes, copy number 9–21 (broad region; genes not listed).
- chr6:60,719,222–63,779,336, 29 genes, copy number 9: GAPDHP41, AL590227.1, AL512427.2, AL512427.1, RBBP4P3, AL356131.1, MTRNR2L9, KHDRBS2-OT1, KHDRBS2, AL355347.1, DHFRP5, AL355375.1, AL355375.2, AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3.
- chr6:63,797,189–63,857,769, 3 genes, copy number 9: AL354719.1, SCAT8, GCNT1P4.
- chr6:64,631,205–64,631,682, 1 gene, copy number 12: HNRNPDP2.
- chr7:54,656,358–57,837,046, 149 genes, copy number 10 (broad region; genes not listed).
- chr9:1,977,784–11,013,096, 124 genes, copy number 9–48 (broad region; genes not listed).
- chr11:70,477,277–70,604,859, 2 genes, copy number 7: AP001271.1, AP001271.2.
- chr11:133,297,189–135,075,908, 35 genes, copy number 7: AP003972.1, OPCML-IT1, AP004606.1, LINC02743, SPATA19, AP001979.1, IGSF9B, MIR4697, LINC02730, LINC02731, AP000911.1, JAM3, PTP4A2P2, NCAPD3, AP001775.1, AP001775.2, VPS26B, THYN1, ACAD8, GLB1L3, AP000859.1, GLB1L2, B3GAT1, B3GAT1-DT, AP004550.1, AP001999.3, AP001999.1, AP001999.2, LINC02706, LINC02714, AP003062.2, LINC02697, AP003062.1, LINC02717, LINC02684.
- chr17:27,411,438–29,567,037, 131 genes, copy number 9 (broad region; genes not listed).
- chr17:29,566,052–29,573,157, 2 genes, copy number 9: TP53I13, AC104564.3.
- chr18:47,390–976,883, 36 genes, copy number 9: TUBB8B, AP001005.3, IL9RP4, AP001005.2, ROCK1P1, MIR8078, USP14, THOC1, AP000845.1, AP000915.1, COLEC12, AP000915.2, LINC01925, CETN1, RN7SKP146, CLUL1, AP001178.4, TYMSOS, AP001178.3, AP001178.1, TYMS, ENOSF1, AP001178.2, YES1, AP001020.3, AP001020.1, AP001020.2, RNU1-109P, AP000894.4, BOLA2P1, AP000894.1, AP000894.3, AP000894.2, ADCYAP1, LINC01904, AP005328.1.
- chr18:1,883,524–2,489,426, 1 gene, copy number 7 (within-gene range 5–11): AP005230.1.
- chr18:2,506,628–5,630,700, 69 genes, copy number 10–11 (broad region; genes not listed).
- chr18:8,471,831–9,254,346, 17 genes, copy number 9 (within-gene range 3–9): RN7SL50P, THEMIS3P, AKR1B1P6, RAB12, AP001793.1, TOMM20P3, GACAT2, MTCL1, Y_RNA, AP000864.1, AP001531.1, AP005899.2, RPS4XP19, NDUFV2, AP005263.1, AP005899.1, NDUFV2-AS1.
- chr18:54,717,860–55,146,645, 8 genes, copy number 7: RAB27B, RPSAP57, AC007673.1, AC098848.1, CCDC68, MAP1LC3P, LINC01929, RNA5SP459.
- chr19:49,368,558–50,310,542, 72 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr20:87,250–13,638,932, 277 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 55. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
